Somatic mutation profile of tumor specimen 0DRZIT from CCDI case PBCFXZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.0 years (2,188 days).
Specimen 0DRZIT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 848ecb59-6963-400d-a883-afc70ad730f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRZJC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dd17ec4-a9f6-4c48-b427-b2d97dede910

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Intron 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C11 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1057519904; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs560787141, COSV100879356, COSV66105839; called by muse, mutect2
- DDX23 | c.867G>T p.L289= | Splice Region (SNP) | VAF 35/549 reads (6%) | catalogued as COSV99076301; called by muse, mutect2
- LILRB1 | c.658G>A p.V220M (on ENST00000427581; = p.V184M on NM_006669.6) | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs376597507, COSV61117652; called by muse, mutect2, varscan2
- NUGGC | c.2169G>T p.E723D | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV58435942; called by muse, mutect2, varscan2
- PPP1R3F | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs782307066; called by muse, mutect2, varscan2
- RASAL3 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1327787958; called by muse, mutect2, varscan2
- BBX | c.1787A>G p.D596G | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 22/774 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DDX20 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, varscan2
- MBTPS2 | c.998A>C p.E333A | Missense Mutation (SNP) | VAF 146/359 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- PGLYRP2 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2
- SLC9A7 | c.1441C>A p.H481N | Missense Mutation (SNP) | VAF 154/476 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SRCAP | c.3370_3371dup p.S1125Pfs*5 | Frame Shift Ins (INS) | VAF 66/152 reads (43%) | called by mutect2, varscan2
- ZNF45 | c.1474A>G p.R492G | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NACAD | c.3952C>T p.L1318= | Silent (SNP) | VAF 11/225 reads (5%) | catalogued as COSV71989509; called by muse, mutect2
- PNPLA8 | c.822G>A p.A274= | Silent (SNP) | VAF 128/306 reads (42%) | catalogued as rs912647726; called by muse, mutect2, varscan2
- SLCO2A1 | c.1278C>T p.A426= | Silent (SNP) | VAF 181/440 reads (41%) | catalogued as rs746875740, COSV60485032; called by muse, mutect2, varscan2
- TONSL | c.2776-38G>T | Intron (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
